Somatic mutation profile of tumor specimen C3N-01177-02 (aliquot CPT0379850009) from CPTAC case C3N-01177, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.8 years (23,681 days).
Specimen C3N-01177-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cecfc0e-e30b-4cc6-8b7a-375d2529c151.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01177-31 (Blood Derived Normal), aliquot CPT0379960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ea45562-d75c-49ca-bb3b-b3c28adeace0

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 3, Silent 2, 5'Flank 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3377A>G p.N1126S | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs777847755, COSV54347133; called by muse, mutect2, varscan2
- FAT3 | c.11891C>T p.A3964V | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV53074397; called by muse, mutect2, varscan2
- IGHV3-23 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 94/766 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); catalogued as rs548183159; called by muse, mutect2, varscan2
- OR4K17 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs187801072; called by muse, mutect2, varscan2
- PAK4 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs906708547; called by muse, mutect2
- PEX14 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs766959628, COSV63061072; called by muse, mutect2
- PRPF6 | c.2205+1G>T p.X735_splice | Splice Site (SNP) | VAF 70/282 reads (25%) | catalogued as rs112093327, COSV53880389; called by muse, mutect2, varscan2
- PTGS1 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs954849919; called by muse, mutect2
- SVIL | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs773284915, COSV63443471; called by muse, mutect2, varscan2
- WNK4 | c.3652_3653del p.L1218Efs*53 | Frame Shift Del (DEL) | VAF 86/413 reads (21%) | catalogued as rs772009924; called by pindel, varscan2
- AFMID | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DCAF4L2 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- FBXW10 | c.1443T>A p.D481E | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FHAD1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECW1 | c.4474C>A p.L1492I | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- KRT6C | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 174/615 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRBA | c.6370G>T p.A2124S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- NME9 | c.767T>A p.V256E (on ENST00000333911 / NM_001349024.2; = p.V195E on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.077); called by muse, mutect2
- PCBP4 | c.901G>A p.A301T (on ENST00000322099 / NM_033010.2; = p.A258T on NM_020418.4) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLP2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 12/412 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC5A12 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PICALM | c.1932A>G p.V644= | Silent (SNP) | VAF 111/365 reads (30%) | called by muse, mutect2, varscan2
- SYT14 | c.1215A>C p.T405= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- BICD1 | c.213+104_213+105del | Intron (DEL) | VAF 56/233 reads (24%) | called by mutect2, pindel, varscan2
- DDX1 | chr2:15591846 G>A | 5'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892909 C>A | 5'Flank (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- SERINC2 | c.39+646C>T | Intron (SNP) | VAF 61/162 reads (38%) | catalogued as rs928432048; called by muse, mutect2, varscan2
- SKP1P2 | n.248A>G | RNA (SNP) | VAF 76/264 reads (29%) | called by muse, mutect2, varscan2
- TSHR | c.692+186C>T | Intron (SNP) | VAF 20/518 reads (4%) | called by muse, mutect2
